Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A69L, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A69L-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph nodes, right pelvic, regional resection
- No evidence of metastatic disease in ten lymph nodes (0/10)
- Follicular lymphoid hyperplasia

B: Lymph nodes, left pelvic, regional resection
- No evidence of metastatic disease in twelve lymph nodes (0/12)
- Follicular lymphoid hyperplasia

C: Cervix, uterus and parametrium, radical hysterectomy

Histologic type: Invasive non-keratinizing squamous cell carcinoma

Histologic grade: moderate to poorly differentiated

Tumor focality/site: (quadrant(s) of cervix) invasive carcinoma
- 6-3 o'clock clockwise (3 quadrants)
CIN3 at 5 o'clock

Tumor size: (greatest dimension) 4.0 cm

Extent of invasion:

Depth: 1.6 cm Wall thickness: 2.3 cm

Percent: 70%

(See sections C6 and C7)

Horizontal extent: 2.7 cm

Lymphovascular space invasion: none identified

Parametrial soft tissue involvement: -no evidence of tumor involvement in the right or left parametrium
-3 benign right parametrial lymph nodes and 1 benign left parametrial lymph node (0/4)

Vaginal cuff involvement: negative, margins clear

Surgical margins: clear

Invasive: carcinoma comes within 0.5 cm of the anterior cervical soft tissue margin at 12 o'clock in section C7 (closest margin)
Intraepithelial: widely free

ICD-O-3

Carcinoma, squamous cell
nonkeratinizing NOS 8574/3

Site Cervix NOS C53.9
JW 5/16/13

[page 2 of 4]
Regional lymph nodes (see other specimens):
Total number involved: 0
Total number examined: 26

Additional pathologic findings:

Endometrium

- Proliferative phase

Myometrium

- Leiomyomata, no significant atypia, mitotic activity, or tumor necrosis identified

AJCC Pathologic Stage: pT1b1 pN0 pMx

Note: This staging information is based on the pathologic specimen and may be incomplete. A comprehensive review of all available clinical information is recommended to determine final staging.

Clinical History:

-year-old with Stage 1B cervical cancer.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "right pelvic lymph node." It consists of a 4.3 x 2.6 x 1.5 cm portion of adipose tissue that is dissected for lymph node candidates of which nine are identified ranging from 0.4 cm in greatest dimension up to 4.3 x 1.5 x 1.2 cm in greatest dimension.

Block summary:

A1 - five lymph nodes

A2 - two lymph nodes

A3 - one lymph node, serially sectioned

A4-A6 - one lymph node, serially sectioned

Container B is additionally labeled "left pelvic lymph node." It consists of a 6.1 x 2.1 x 1.4 cm portion of adipose tissue that is dissected for lymph node candidates of which eleven are identified ranging from 0.4 cm in greatest dimension up to 4.1 x 1.3 x 0.4 cm in greatest dimension.

Block summary:

B1 - four lymph nodes

B2-B7 - each contains one lymph node, serially sectioned

B8-B9 - one lymph node, serially sectioned

[page 3 of 4]
Container C is additionally labeled "uterus, cervix, parametrium."

Specimen fixation: formalin

Specimen type: radical hysterectomy with attached bilateral parametrium

Adnexa: absent

Weight: 345 grams

Shape: distorted pyriform

Dimensions:

Height: 10.5 cm

Anterior to posterior width: 5.2 cm

Breadth at fundus: 7.1 cm

Serosa: pink/tan, smooth and glistening with two homogeneous white whorled rubbery nodules (1.0 x 1.0 x 0.6 cm and 7.1 x 4.7 x 4.6 cm), each of which bulges on cut section; Anterior cervix=blue, posterior cervix=black.

Cervix:

Ectocervix: 4.1 cm in diameter; smooth and gray, of which approximately 75% of the anterior ectocervix is eroded by tumor; the posterior ectocervix has a focus of abutting tumor but is intact, smooth and glistening

Tumor size: 4.0 x 2.7 x 1.5 cm (protruding into the canal)
Tumor site: Tumor involves from 6 o' clock up through 3 o' clock (clockwise fashion) with 3-5 o' clock uninvolved by mass; the mass is soft, tan/yellow, well circumscribed and partially friable but is without hemorrhage or necrosis; the mass partially erodes the anterior ectocervix and grossly abuts the posterior ectocervix, extends 1.2 cm into the stroma, 0.3 cm from the anterior cervical soft tissue margin, 0.9 cm from the posterior cervical soft tissue margin, 1.4 cm from the anterior lower uterine segment, 1.1 cm from the posterior lower uterine segment, and 0.8 cm closest to the vaginal mucosal margin (at 12 o' clock)

Endocervix: involved by mass except from 3-5 o' clock
Other features: none

Endometrium:

Length of endometrial cavity: 3.9 cm

Width: 3.8 cm

Endometrial surface: red/brown, slightly granular (less than 0.1 cm thick)

Other findings: none

[page 4 of 4]
Myometrium:

Thickness of wall: 2.5 cm

Other findings: The myometrium is tan, trabeculated and contains approximately 10 homogenous white whorled rubbery nodules up to 3.5 x 3.5 x 3.0 cm in greatest dimension, all of which bulge on cut section.

Vagina: The vaginal mucosa measures 4.7 cm in diameter x 1.3 cm wide x 0.1 cm thick and is tan, smooth and glistening and unremarkable.

Urinary bladder: n/a

Rectum: n/a

Digital picture: not taken

Tissue give to tissue procurement: Tumor is given to the Tumor Procurement foundation.

Block summary:

- C1 - vaginal mucosal margin, en face from 12 to 3 o' clock
- C2 - vaginal mucosal margin, en face, from 3 to 6 o' clock
- C3 - vaginal mucosal margin, en face, from 6 to 9 o' clock
- C4 - vaginal mucosal margin, en face, from 9 to 12 o' clock
- C5 - perpendicular of mass at 9 o' clock with vaginal mucosa
- C6-C8 - cervix, 12 o' clock, longitudinal section from ectocervix through the anterior lower uterine segment, one piece trisected (C6 contains mass eroding through ectocervix, C7 has vaginal mucosa and cervical soft tissue, C8 is anterior lower uterine segment with intramural nodule)
- C9 - perpendicular of mass at 3 o' clock
- C10 - perpendicular of cervix at 5 o' clock
- C11-C13 - cervix at 6 o' clock, one full length longitudinal section from ectocervix towards posterior lower uterine segment, one piece, trisected (C11 has mass with ectocervix and vaginal mucosa, C12 is mass within endocervical canal, C13 is posterior lower uterine segment)
- C14 - perpendicular cervix at approximately 8 o' clock with mass
- C15-C16 - anterior corpus, full thickness, bisected, with subserosal nodule
- C17-C18 - posterior corpus, full thickness, bisected with intramural nodule
- C19-C21 - intramural nodules
- C22-C24 - largest subserosal nodule
- C25-C29 - right lateral parametrial soft tissue, serially sectioned
- C30-C34 - left parametrial soft tissue, serially sectioned

Diagnosis Uncertainty		
Primary / Tumor Site Discrepancy		
IHFA Discrepancy		
PRC Metastatic History		
Dual/Trichromatic Primary		
Case is (check)		
Reviewed Initial		
Reviewed		
DATE		

4/ 5/3/13

122112

Source: NCI Genomic Data Commons file 9f7b2565-9fea-4f56-a386-98aea7b3b6c7 (TCGA-EX-A69L.6B157876-04F4-49D6-BACB-87F8E2B921CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).